Gene-level copy-number profile of tumor specimen TCGA-23-1029-01B from TCGA case TCGA-23-1029, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 46.2 years (16,889 days).
Specimen TCGA-23-1029-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.050b0445-dde0-48c6-9a0f-9c041567cf3a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-23-1029-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/0352a229-5724-43c4-8b22-01d7bc4704e6

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 45; copy number 1: 17,123; copy number 2: 34,245; copy number 3: 5,806; copy number 4: 2,060; copy number 5: 144; copy number 6: 169; copy number 7: 228.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-23-1029-01B-01D-0577-01): tumor purity 0.83, ploidy 1.92, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 45 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:2,474,844–5,306,870, 45 genes (within-gene range 0–1): GRIFIN, LFNG, MIR4648, BRAT1, IQCE, TTYH3, AMZ1, GNA12, AC006028.1, CARD11, CARD11-AS1, RN7SKP130, AC024028.1, AC073316.1, AC073316.2, SDK1-AS1, SDK1, AC092427.1, AC011284.1, AC017000.1, CYP3A54P, AC072054.1, FOXK1, AC092428.1, AP5Z1, MIR4656, AC092610.1, RADIL, Y_RNA, PAPOLB, RPL22P16, MMD2, RNF216P1, AC092032.2, RBAK-RBAKDN, AC092032.3, AC092032.1, SPDYE19P, RBAK, RBAKDN, OR10AH1P, ZNF890P, RNU6-215P, WIPI2, SLC29A4.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 541 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:14,152,196–14,211,186, 1 gene, copy number 5 (within-gene range 4–5): AL133259.1.
- chr6:14,210,293–16,295,549, 32 genes, copy number 5: AL353152.2, AL353152.1, LINC01108, AL080313.2, AL080313.1, AL009177.1, AL109914.1, RNU6-793P, AL138720.1, AL050335.1, RN7SL332P, AL136162.1, JARID2, JARID2-AS1, RNU6-522P, RNU6-645P, 5S_rRNA, DTNBP1, AL021978.1, ARPC3P5, LINC02543, AL365265.1, MDH1P2, MYLIP, MIR4639, AL021407.2, AL021407.1, MRPL42P2, RNU6-1114P, Y_RNA, GMPR, AL009031.1.
- chr8:114,791,653–145,066,685, 508 genes, copy number 5–7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 14,702. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
